Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1A3, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1A3-01A (Primary Tumor).

[page 1 of 6]
1CD-0-3

Carcinoma, urothelial, NOS 8120/3

Site Code: bladder, NOS C67.9

12/30/10

SURGICAL PATHOLOGY REPORT**Patient Name:****Med. Rec. #:**

DOB: (Age: 61)

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type: INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Muscle invasive urothelial carcinoma of the bladder, bilateral hydronephrosis

Specimens Submitted:

- 1: SP: URETHRA, DISTAL MARGIN, EXCISION
- 2: SP: LYMPH NODES, LEFT PELVIC, EXCISION
- 3: SP: LYMPH NODES, RIGHT PELVIC, EXCISION
- 4: SP: BLADDER, URACHUS, URETHRA, PROSTATE, SEMINAL VESICLES, PERVESICLE TISSUE, LYMPH NODES, DISTAL URETERS, PORTIONS OF BIALTERAL STENTS, RADICAL CYSTECTOMY
- 5: SP: VAS DEFERENS, LEFT, EXCISION
- 6: SP: URACHUS, EXCISION
- 7: SP: VAS DEFERENS, RIGHT, EXCISION
- 8: SP: URETERAL STENT, RIGHT, REMOVAL
- 9: SP: PERIURETERAL TISSUE, LEFT, EXCISION
- 10: SP: URETERAL STENT, LEFT, REMOVAL
- 11: SP: URETHRA, DISTAL MARGIN, EXCISION
- 12: SP: URETER, DISTAL LEFT, EXCISION
- 13: SP: URETER, LEFT DISTAL, HIGH PROXIMAL MARGIN, EXCISION
- 14: SP: URETER, DISTAL RIGHT, EXCISION

DIAGNOSIS:

1. SP: URETHRA, DISTAL MARGIN, EXCISION:

Benign fibromuscular tissue

2. SP: LYMPH NODES, LEFT PELVIC, EXCISION:

Lymph Nodes:

Number of nodes examined:9

Number of metastatic nodes:5

The largest metastatic node is 3.4cm

Perinodal (extracapsular) extension identified

Metastatic high grade urothelial carcinoma

3. SP: LYMPH NODES, RIGHT PELVIC, EXCISION:

Lymph Nodes:

Number of nodes examined:9

Number of metastatic nodes:7

The largest metastatic node is 3.2cm

Perinodal (extracapsular) extension not identified

Metastatic high grade urothelial carcinoma

4. SP: BLADDER, URACHUS, URETHRA, PROSTATE, SEMINAL VESICLES, PERVESICLE TISSUE, LYMPH NODES, DISTAL URETERS, PORTIONS OF BIALTERAL STENTS, RADICAL CYSTECTOMY:

Tumor Type:

Invasive urothelial carcinoma, NOS

Invasive urothelial carcinoma, NOS with diffuse growth pattern and focal micropapillary features

Histologic Grade:

H/PA Discrepancy		X

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

High grade

Pattern of growth of the Non-Invasive component:
Papillary and flat

Pattern of growth of the Invasive component:
Diffuse

Tumor Multicentricity:
Identified

Bladder Local Invasion:
Perivesical soft tissues

Extravesical Tumor Extension:
Urethra uninvolved
Prostatic stroma involved

Vascular Invasion:
Identified

Perineural Invasion:
Identified

Surgical Margins:
Tumor present at urethral margin
Urothelial carcinoma in situ present at right ureteral margin (see part 14 for final margin status); Invasive urothelial carcinoma present at urethral margin (see specimens 1 and 12 for additional urethral margins)

Non-Neoplastic Mucosa:
Exhibiting chronic cystitis
Exhibiting foreign body reaction
Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

Prostate:
Nodular hyperplasia
Other ; involved by invasive urothelial carcinoma

Seminal Vesicles:
Other Involved by urothelial carcinoma

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC 2002):
pT3 (Invasion of perivesicle soft tissue)

PR2 (Periprostic or periseminal vesicle soft tissue invasion) tissue invasion)

5. SP: VAS DEFERENS, LEFT, EXCISION:
Benign vas deferens

6. SP: URACHUS, EXCISION:
Benign fibroadipose tissue, muscle, and nerve

7. SP: VAS DEFERENS, RIGHT, EXCISION:
Benign vas deferens

8. SP: URETERAL STENT, RIGHT, REMOVAL:
Ureteral stent (gross diagnosis only)

9. SP: PERIURETERAL TISSUE, LEFT, EXCISION:
Invasive high grade urothelial carcinoma involving fibroadipose tissue

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

10. SP: URETERAL STENT, LEFT, REMOVAL:

Ureteral stent (gross diagnosis only)

11. SP: URETHRA, DISTAL MARGIN, EXCISION:

Invasive high grade urothelial carcinoma involving peri-urethral tissue

12. SP: URETER, DISTAL LEFT, EXCISION:

Benign ureter

13. SP: URETER, LEFT DISTAL, HIGH PROXIMAL MARGIN, EXCISION:

Benign ureter

14. SP: URETER, DISTAL RIGHT, EXCISION:

Benign ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "distal margin urethra" and consists of a fragment of tan-red soft tissue measuring 1.3 x 1.0 x 0.4 cm. Entirely submitted for frozen section.

Summary of sections: FSC – frozen section control

2) The specimen is received fresh, labeled "left pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 3.4 cm in greatest dimension. A portion of the specimen is sent for TPS. All identified lymph nodes are submitted in seven cassettes. Summary of sections: LN – lymph nodes, BLN – bisected lymph node

3) The specimen is received fresh, labeled "right pelvic lymph nodes," and consists of multiple pink tan firm lymph nodes ranging from 0.4 to 4 cm in greatest dimension. A portion of the specimen is sent for TPS. All identified lymph nodes are submitted in eight cassettes. Summary of sections: LN – lymph nodes, BLN – bisected lymph node

4) The specimen is received fresh labeled, "bladder, urachus, urethra, prostate, seminal vesicles, perivesicle tissue and lymph nodes, distal ureters, portions of bilateral ureteral stents". It consists of a cystoprostatectomy measuring 13 cm from superior to inferior, 8.5 cm laterally and 4.5 cm from anterior to posterior. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal an ulcerated tumor mass measuring 3 x 1 cm which is grossly situated within the trigone area. The lesion measures 0.3 cm from the left orifice and is present at the right. Two green ureteral stents are present measuring 8.5 and 12 cm in length by 0.2 cm in diameter. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal apparent invasion into the bladder wall/prostate up to 0.6 cm. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is hemorrhagic and verrucated without other mass lesions. Discrete perivesical lymph nodes are grossly not identified. Definite urachal remnant is not identified. The prostate is serially sectioned to reveal unremarkable prostatic parenchyma. Representative sections are submitted including two sections from each prostatic quadrant and transition zone. TPS is submitted. Gross photographs are taken.

Summary of sections: UTHM – urethral margin, RUM – right ureter margin, LUM – left ureter margin, L – lesion
RUO – right ureter orifice, LUO – left ureter orifice, LP – left posterior wall, LA – left anterior wall, RP – right posterior wall
RA – right anterior wall, TRI – trigone, DOM – dome, U – urachal area, F – perivesical fat, RSV – right seminal vesicle
LSV – left seminal vesicle, RA – right apex prostate, LA – left apex prostate, RAM – right anterior mid prostate
RPM – right posterior mid prostate, LAM – left anterior mid prostate, LPM – left posterior mid prostate, RAB – right anterior base prostate, RPB – right posterior base prostate, LAB – left anterior base prostate, LPB – left posterior base prostate

5) The specimen is received in formalin, labeled "Left vas deferens" and consists of a segment of tan tubular elastic tissue, with attached small amount of unremarkable fat, measuring 10 cm in length and 0.2 cm in diameter. Representatively submitted.
Summary of sections: BE – both ends, RS – representative sections

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

- 6) The specimen is received in formalin, labeled " " and consists of a 1.5 x 1.2 x 0.4 cm fragment of yellow tan adipose soft tissue. Bisected and entirely submitted. Summary of sections: U - undesignated
- 7) The specimen is received in formalin, labeled "Right vas deferens" and consists of an unoriented segment of tan elastic tissue, measuring 3 cm in length and 0.2 cm in average diameter. Entirely submitted.
Summary of sections: BE - both ends, RT - remaining tissue
- 8) The specimen is received fresh labeled, "Portion of right ureteral stent" and consists of an elongated tubular green stent measuring 27 x 0.2 cm. The specimen is photographed. Gross only.
- 9) The specimen is received in formalin, labeled "Peri urethral tissue left" and consists of a 1 x 1 x 0.4 cm fragment of tan soft tissue. Bisected and entirely submitted. Summary of sections: U - undesignated
- 10) The specimen is received fresh labeled, "Portion of left ureteral stent" and consists of an elongated tubular green stent measuring 25 x 0.2 cm. The specimen is photographed. Gross only.
- 11) The specimen is received in formalin, labeled "Distal margin urethra" and consists of two fragments of tan soft tissue, measuring 0.9 x 0.5 x 0.1 and 0.7 x 0.5 x 0.2 cm. Entirely submitted. Summary of sections: U - undesignated
- 12) The specimen is received in formalin, labeled "Distal left ureter" and consists of a 1.5 x 0.7 x 0.3 cm fragment of tan soft tissue. Entirely submitted. Summary of sections: U - undesignated
- 13) The specimen is received in formalin, labeled "High proximal margin left ureter, distal" and consists of a 1.6 x 0.8 x 0.2 cm piece of tan soft tissue. Entirely submitted. Summary of sections: U - undesignated
- 14) The specimen is received in formalin, labeled "Distal right ureter clip on proximal margin" and consists of a 1.5 x 1.5 x 1 cm tubular piece of tan soft tissue, consistent with a dilated ureter. A clip demarcating the proximal margin is identified. Entirely submitted. Summary of sections: UE - unclipped end, CE - clipped end, RT - remaining tissue

Summary of Sections:

Part 1: SP: URETHRA, DISTAL MARGIN, EXCISION (FS)

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: LYMPH NODES, LEFT PELVIC, EXCISION

Block	Sect. Site	PCs
2	BLN	2
5	LN	8

Part 3: SP: LYMPH NODES, RIGHT PELVIC, EXCISION

Block	Sect. Site	PCs
2	BLN	2
6	LN	8

Part 4: SP: BLADDER, URACHUS, URETHRA, PROSTATE, SEMINAL VESICLES, PERIVESICLE TISSUE, LYMPH NODES, DISTAL URETERS, PORTIONS OF BILATERAL STENTS, RADICAL CYSTECTOMY

Block	Sect. Site	PCs
1	DOM	1
1	F	1
4	L	4
2	LA	2

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

1	LAB	1
1	LAM	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
2	RA	2
1	RAB	1
1	RAM	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
1	TRI	1
1	U	1
1	UTHM	1

Part 5: SP: VAS DEFERENS, LEFT, EXCISION

Block	Sect. Site	PCs
1	BE	2
1	RS	5

Part 6: SP: URACHUS, EXCISION

Block	Sect. Site	PCs
1	U	2

Part 7: SP: VAS DEFERENS, RIGHT, EXCISION

Block	Sect. Site	PCs
1	BE	2
2	RT	6

Part 8: SP: URETERAL STENT, RIGHT, REMOVAL

Part 9: SP: PERIURETERAL TISSUE, LEFT, EXCISION

Block	Sect. Site	PCs
1	U	2

Part 10: SP: URETERAL STENT, LEFT, REMOVAL

Part 11: SP: URETHRA, DISTAL MARGIN, EXCISION

Block	Sect. Site	PCs
1	U	2

Part 12: SP: URETER, DISTAL LEFT, EXCISION

Block	Sect. Site	PCs
1	U	1

Part 13: SP: URETER, LEFT DISTAL , HIGH PROXIMAL MARGIN, EXCISION

Block	Sect. Site	PCs
1	U	1

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Part 14: SP: URETER, DISTAL RIGHT, EXCISION

Block	Sect. Site	PCs
1	CE	1
2	RT	2
1	UE	1

HPA Discrepancy		

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Distal margin urethra): BENIGN MARGIN
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 78ea760d-87b7-46e5-bee9-5ea2e27b6da4 (TCGA-DK-A1A3.2FDD45DD-21FB-492B-8458-6D96FBF46509.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).